CPTAC case C621273 — Colon — Epithelial Neoplasms, NOS (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Epithelial Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/930911b1-c2b6-4e21-933c-8978b16a8de2

Demographics
Sex at birth: female; Age at index: 71 years; Vital status: Dead; Days to death: 213 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cerebrum; Last known disease status: With tumor; Days to last known disease status: 213 days; Progression or recurrence: yes; Days to recurrence: 102 days; Sites of involvement: Brain, Cerebrum; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 30; Cigarettes per day: 20; Alcohol history: Yes.

Biospecimens (5 samples)
- Samples 1104792, 1105255, SM-JU34H, SM-JU34T (4 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Left; Preservation method: Snap Frozen.
- Sample 1105218: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
